Surgical pathology report (de-identified scan), TCGA case TCGA-85-8277, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8277-01A (Primary Tumor).

[page 1 of 3]
[Redacted]

Case ID	Gross Description	Microscopic Description	Diagnosis Details	Comments
[Redacted]				

[page 2 of 3]
Formatted Path Report

LUNG TISSUE CHECKLIST

Specimen type: Pulmonectomy
Tumor site: Lung
Tumor size: 10 x 10 x 8 cm
Histologic type: Squamous cell carcinoma
Histologic grade: Not specified
Tumor extent: Visceral pleura
Other tumor nodules: Not specified
Lymph nodes: 4/4 positive for metastasis (Intrathoracical 4/4)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

ica ID

[page 3 of 3]
Excision date	Lateralit y
	Left- upper

Source: NCI Genomic Data Commons file 17e5b5f3-abee-4b7f-9f1b-147e810aea1a (TCGA-85-8277.60C19484-4FC6-4838-A9B9-527F4E79F93E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).